Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A40M, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A40M-01A (Primary Tumor).

[page 1 of 3]
Referring Physician:

DOB: Age: Gender

Ref#: Hosp#: Provider Group:

Date of Service: Date Received: Outpatient
Room: Bed: Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

1C0-0-3

path: carcinoma, papillary
Follicular variant 9340/3

CCF: carcinoma, papillary,
thyroid 8260/3

Site: thyroid, NOS

7-3-12 ED C73.4

A. THYROID GLAND, TOTAL THYROIDECTOMY:

- PAPILLARY CARCINOMA, FOLLICULAR VARIANT, MULTIFOCAL

- Largest focus, left lobe, 1.7 cm in maximum dimension.

- Second focus, right lobe, 0.1 cm in greatest dimension.

- MARGIN STATUS: NEGATIVE.

- Tumor is 0.01 cm from the posterior margin of the left lobe.

- EXTRATHYROIDAL EXTENSION: NOT IDENTIFIED.

- NO PARATHYROID TISSUE IDENTIFIED.

- SEE PATHOLOGIC TUMOR STAGING SUMMARY BELOW.

B. CENTRAL NODE TISSUE, EXCISION:

- FIVE LYMPH NODES, NEGATIVE FOR METASTASIS (0/5).

PATHOLOGIC TUMOR STAGING SUMMARY:

Tumor type: Papillary thyroid carcinoma, follicular variant.

Primary tumor: pT1b (largest focus, 1.7 cm in greatest dimension,
limited to the thyroid).

Regional lymph nodes: pN0 (0/5 lymph nodes).

Distant metastasis: Not applicable.

Tumor stage: I.

Lymphovascular invasion: Not identified.

Margin status: R0 (0.01 cm from posterior margin of left lobe).

Per TSS, follicular variant < 99%

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, Ed, and CAP protocol,

Case #:

Printed:

Phone

Page 1

This report continues... (FINAL)

Patient Narr

[page 2 of 3]
Patient: [Redacted]

Case #: [Redacted]

Procedure:

Specimen type:
Specimen integrity:
Specimen size:

Total thyroidectomy with central compartment
dissection.
Thyroid gland.
Intact.
Right lobe: 3.7 x 1.8 x 1.3 cm.
Left lobe: 3.7 x 2.1 x 1.5 cm.
Isthmus: 1.8 x 1.5 x 0.5 cm.

TUMOR FEATURES:

Tumor size:

Tumor focality:
Tumor laterality:
Histologic type:
Lymphovascular invasion:
Tumor capsule:
Tumor capsular invasion:
Extrathyroidal extension:

Largest focus, greatest dimension, 1.7 cm; additional
dimensions, 1.5 x 1.4 cm.
Second focus, greatest dimension, 0.1 cm.
Multifocal
Both lobes.
Papillary carcinoma, follicular variant.
Not identified.
Partially encapsulated.
Not identified.
Not identified.

LYMPH NODES:

Five lymph nodes, negative for metastasis (0/5).

MARGIN EVALUATION:

Distance to closest margin:
Other margins:

Negative (R0).
0.01 cm from posterior margin, left lobe.
0.06 cm from anterior left lobe margin; all other margins
at least 0.1 cm.

PATHOLOGIC TUMOR STAGING DESCRIPTORS:

Primary tumor:

Regional lymph nodes:
Distant metastasis:
Margin status:
Pathologic stage:

pT1b (largest lesion, 1.7 cm in greatest dimension,
limited to the thyroid).
pN0 (0/5 lymph nodes).
Not applicable.
R0.
I.

Additional pathologic findings:

Multiple adenomatoid nodules (multinodular goiter) with
Hurthle cell change.
Not applicable.

Comment:

Case #: [Redacted]

Printed: [Redacted]

Page 2

This report continues... (FINAL)

[page 3 of 3]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Thyroid
- B. Lymph node; Central node

Clinical History/Operative Dx:

Thyroid cancer

Gross Description:

A. The specimen is labeled total thyroid and is received without fixative. It consists of a total thyroidectomy specimen weighing 14 grams. A suture marks the left lobe. The right lobe measures 3.7 x 1.8 x 1.3 cm and the left lobe measures 3.7 x 2.1 x 1.5 cm. There is a triangular portion of isthmus which measures 1.8 x 1.5 x 0.5 cm. There are no grossly obvious parathyroid glands. The anterior right thyroid is inked blue, the anterior left thyroid is inked green, the anterior isthmus is inked yellow, and the posterior surfaces are inked black. The thyroid lobes and isthmus are serially sectioned to reveal a sharply circumscribed tan-white neoplasm in the superior third of the left thyroid lobe. It measures 1.7 x 1.5 x 1.4 cm. It appears contained within the thyroid gland. Representative sections of the neoplasm are obtained for research purposes. Elsewhere within the left thyroid lobe and also in the right thyroid lobe there is a beefy dark red thyroid gland parenchyma and areas of colloid-like change, but no other discrete masses. The specimen is entirely submitted as summarized below. Section summary:
A1-A6) left thyroid lobe submitted from superior-inferior,
A7-A11) right thyroid lobe submitted from superior-inferior,
A12-A13) isthmus.

B. The specimen is labeled central node and is received in formalin. It consists of multiple fragments of fibrofatty tissue which are 2 cm in aggregate. On gentle palpation there appears to be a possible 0.3 cm pale red lymph node. The specimen is submitted intact in cassette B1.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Case #:

Printed:

Page 3

END OF REPORT (FINAL)

Source: NCI Genomic Data Commons file 27c8d937-e39a-4bd2-a458-130d47223267 (TCGA-FY-A40M.868F9544-F5A4-43EC-9031-6F701E82E6FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).